Somatic mutation profile of tumor specimen 94176301-9658-4151-9110-5139de (aliquot 94176301-9658-4151-9110-5139de_D6_1) from CPTAC case 11BR020, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 37.5 years (13,687 days).
Specimen 94176301-9658-4151-9110-5139de: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4915670d-3769-4d54-9d10-859ed582f32c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 04bb91d9-92af-4fe1-b02a-9972ac (Blood Derived Normal), aliquot 04bb91d9-92af-4fe1-b02a-9972ac_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eada8ccb-9315-4f68-8a00-dbe43f184908

The open-access MAF lists 141 somatic variants for this specimen: 96 protein-altering or splice-affecting, 31 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 31, Nonsense Mutation 9, Intron 8, 5'UTR 3, Frame Shift Del 2, Splice Region 2, Splice Site 2, 5'Flank 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 183/575 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCC8 | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs779888804; called by muse, mutect2
- AHNAK | c.14212G>A p.D4738N | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs529008518; called by muse, mutect2, varscan2
- ATOH1 | c.506G>C p.R169P | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs758188041; called by muse, mutect2, varscan2
- C10orf62 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 13/121 reads (11%) | catalogued as COSV101035325; called by muse, mutect2, varscan2
- CDK5R1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55581590; called by muse, mutect2, varscan2
- CRLF2 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1361857498; called by muse, mutect2
- CTBP2 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58337054; called by muse, mutect2
- EDN3 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 159/631 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV61107748; called by muse, mutect2, varscan2
- FAM83E | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 48/398 reads (12%) | catalogued as rs1214930179; called by muse, mutect2, varscan2
- GGA2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs780516710, COSV59167613; called by muse, mutect2, varscan2
- GPR15 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs776909640; called by muse, mutect2, varscan2
- ITPKC | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 80/336 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as rs775698126; called by muse, mutect2, varscan2
- ITPR2 | c.7857+1G>C p.X2619_splice | Splice Site (SNP) | VAF 24/86 reads (28%) | catalogued as rs1242494242; called by muse, mutect2, varscan2
- KAT6B | c.5254C>G p.Q1752E | Missense Mutation (SNP) | VAF 75/774 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs924532501; called by muse, mutect2
- KRT20 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV51424410; called by muse, mutect2, varscan2
- MAP4K3 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55712844; called by muse, mutect2, varscan2
- MDM2 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.311); catalogued as rs777969898; called by muse, mutect2
- MEF2C | c.258G>A p.E86= | Splice Region (SNP) | VAF 36/142 reads (25%) | catalogued as rs1554139682, CM1415071; called by muse, mutect2, varscan2
- METTL2B | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.044); catalogued as COSV52310452; called by muse, mutect2
- MRGPRF | c.243C>G p.Y81* | Nonsense Mutation (SNP) | VAF 58/321 reads (18%) | catalogued as rs1406201444; called by muse, mutect2, varscan2
- MUC12 | c.15575C>T p.S5192F (on ENST00000379442; = p.S5049F on NM_001164462.1) | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); catalogued as rs1312001322; called by muse, mutect2, varscan2
- OR10P1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs374603359, COSV59006615; called by muse, mutect2, varscan2
- P3H2 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as rs1402008311; called by muse, mutect2, varscan2
- PCDHA5 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 51/598 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs782698382, COSV65350502; called by muse, mutect2
- PHLDB2 | c.1554C>A p.D518E | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs777408728; called by muse, mutect2, varscan2
- RMDN3 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs762671209; called by muse, mutect2, varscan2
- SPTA1 | c.4069G>A p.D1357N | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.028); catalogued as rs746616673, COSV63751723; called by mutect2, varscan2
- SPTA1 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 51/469 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV63757892; called by muse, mutect2, varscan2
- STOX1 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV100058168; called by muse, mutect2, varscan2
- TAF1 | c.2300C>A p.P767H (on ENST00000373790 / NM_138923.4; = p.P788H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52121930; called by muse, mutect2
- TCF12 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.037); catalogued as COSV99978146; called by muse, mutect2, varscan2
- TCHH | c.2476G>C p.E826Q | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV100915094; called by muse, mutect2
- TMPRSS2 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100152184; called by muse, mutect2, varscan2
- TRBV7-1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs1160267034; called by muse, mutect2, varscan2
- TSPYL4 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60305651; called by muse, mutect2, varscan2
- UBR1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51935864; called by muse, mutect2
- USP45 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59679082; called by muse, mutect2, varscan2
- ZNF672 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs371348856, COSV60637620; called by muse, mutect2, varscan2
- ABCA13 | c.8218T>G p.C2740G | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ABTB2 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADGRG4 | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD18B | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ARAP2 | c.3991G>A p.E1331K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARSF | c.1658C>G p.S553* | Nonsense Mutation (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- ATXN1 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 120/670 reads (18%) | SIFT tolerated, low confidence (0.94); called by mutect2, varscan2
- ATXN1L | c.140G>C p.R47P | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- C9orf131 | c.2402G>C p.R801T | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); called by mutect2, varscan2
- CACNB4 | c.598+3G>A | Splice Region (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- CCT3 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CDH6 | c.2287G>C p.D763H | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CHD6 | c.1437-2A>G p.X479_splice | Splice Site (SNP) | VAF 31/218 reads (14%) | called by muse, varscan2
- CLIC3 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COL18A1 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CRIM1 | c.1466A>C p.D489A | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRYBB1 | c.326T>A p.F109Y | Missense Mutation (SNP) | VAF 153/473 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CTNNB1 | c.1918C>G p.L640V | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DCST2 | c.993del p.L332Cfs*18 | Frame Shift Del (DEL) | VAF 33/350 reads (9%) | called by mutect2, pindel, varscan2
- ESCO1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM189A2 | c.782G>C p.R261T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLT1 | c.3755C>G p.S1252C | Missense Mutation (SNP) | VAF 82/449 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FRMD7 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 43/410 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRB7 | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- GTF3C1 | c.3021C>G p.I1007M | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- HIF1A | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HNRNPC | c.871G>T p.E291* (on ENST00000420743; = p.E278* on NM_004500.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
- IL6ST | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- INTS4 | c.2175G>A p.M725I | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- KIF1B | c.4103C>G p.S1368C (on ENST00000377086 / NM_001365952.1; = p.S1322C on NM_015074.3) | Missense Mutation (SNP) | VAF 37/377 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MYO9A | c.5897A>G p.N1966S | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.114); called by muse, mutect2
- MYO9A | c.344C>G p.S115* | Nonsense Mutation (SNP) | VAF 26/169 reads (15%) | called by muse, mutect2, varscan2
- NLGN4X | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 40/467 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.709); called by muse, mutect2
- OCLN | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.432); called by muse, varscan2
- PEAK1 | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- PI4KA | c.6112G>C p.V2038L | Missense Mutation (SNP) | VAF 46/473 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- POTEE | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 14/233 reads (6%) | called by muse, mutect2
- PRPF40A | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- REM1 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIOK1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RMDN3 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SERPIND1 | c.1127G>C p.R376P | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SHD | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SMG8 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- SRGAP1 | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- STX8 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TBCC | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2
- TLR3 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 58/250 reads (23%) | called by mutect2, varscan2
- TMEM200C | c.507del p.L171Sfs*91 | Frame Shift Del (DEL) | VAF 32/199 reads (16%) | called by mutect2, pindel, varscan2
- TRAV16 | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- VARS1 | c.2302G>C p.A768P | Missense Mutation (SNP) | VAF 89/427 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WASHC5 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 26/399 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); called by muse, mutect2
- WBP2NL | c.413G>C p.R138P | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZMYND12 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF460 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF609 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ZNF774 | c.570G>C p.Q190H | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- AFF2 | c.1281G>A p.L427= | Silent (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- AL645922.1 | c.1722G>A p.Q574= | Silent (SNP) | VAF 74/534 reads (14%) | called by mutect2, varscan2
- BRCA2 | c.4473G>A p.L1491= | Silent (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- CAPG | c.1032C>T p.F344= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV55707305; called by muse, mutect2, varscan2
- CREBZF | c.1038G>A p.R346= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- FGD4 | c.1290C>A p.L430= | Silent (SNP) | VAF 53/247 reads (21%) | called by muse, mutect2, varscan2
- FMN2 | c.2487G>A p.P829= | Silent (SNP) | VAF 86/492 reads (17%) | catalogued as rs1372491335, COSV60431909; called by mutect2, varscan2
- GFI1 | c.183G>C p.L61= | Silent (SNP) | VAF 18/221 reads (8%) | called by muse, mutect2
- GIT2 | c.1752G>A p.Q584= (on ENST00000355312 / NM_057169.5; = p.Q506= on NM_014776.5) | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- GRIN2B | c.831C>T p.L277= | Silent (SNP) | VAF 128/473 reads (27%) | called by muse, mutect2, varscan2
- ICAM1 | c.1323C>T p.I441= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs760839324; ClinVar: likely benign; called by muse, mutect2, varscan2
- ILF3 | c.306C>T p.L102= | Silent (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- KDM6A | c.1767C>T p.D589= | Silent (SNP) | VAF 54/766 reads (7%) | called by muse, mutect2
- LASP1 | c.711C>T p.D237= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as rs746197131, COSV58803016; called by muse, mutect2, varscan2
- MAP6 | c.1512C>G p.V504= | Silent (SNP) | VAF 20/174 reads (11%) | called by muse, mutect2, varscan2
- MARK1 | c.2100G>A p.L700= | Silent (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- MECOM | c.3012C>T p.S1004= (on ENST00000468789 / NM_001105078.4; = p.S1192= on NM_004991.4) | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- MIA3 | c.4989G>A p.Q1663= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- NCAM2 | c.1320C>T p.V440= | Silent (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- OST4 | c.72C>T p.L24= | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as rs1276862722; called by muse, mutect2, varscan2
- PKDREJ | c.1413T>C p.I471= | Silent (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2
- PRRC2B | c.1113C>T p.G371= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- PTBP1 | c.1332G>A p.K444= (on ENST00000349038 / NM_031991.4; = p.K470= on NM_002819.5) | Silent (SNP) | VAF 56/320 reads (18%) | catalogued as rs1162685744; called by muse, mutect2, varscan2
- RUFY2 | c.1125C>T p.I375= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV56260562; called by muse, mutect2, varscan2
- SLFN13 | c.2370C>G p.T790= | Silent (SNP) | VAF 91/482 reads (19%) | called by muse, mutect2, varscan2
- SMARCA5 | c.1515C>T p.F505= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV51644528; called by muse, mutect2
- TRAV38-2DV8 | c.324G>A p.A108= | Silent (SNP) | VAF 70/251 reads (28%) | catalogued as rs61732714; called by muse, mutect2, varscan2
- TRAV8-2 | c.201G>A p.L67= | Silent (SNP) | VAF 59/309 reads (19%) | called by muse, mutect2, varscan2
- ZNF585A | c.108C>T p.F36= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- ZNF609 | c.1350G>C p.L450= | Silent (SNP) | VAF 34/374 reads (9%) | called by muse, mutect2
- ZSCAN10 | c.1956G>A p.R652= (on ENST00000252463; = p.R707= on NM_032805.3) | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs1281725335; called by muse, mutect2, varscan2
- ANKRD33 | c.-6+76G>A | Intron (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- BPIFB1 | c.662-763G>C | Intron (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- BVES | chr6:105137911 A>C | 5'Flank (SNP) | VAF 16/235 reads (7%) | catalogued as rs1178919243; called by muse, mutect2
- DNAJC19 | c.-92del | 5'UTR (DEL) | VAF 35/284 reads (12%) | called by mutect2, pindel, varscan2
- DUSP22 | c.-18C>T | 5'UTR (SNP) | VAF 23/267 reads (9%) | catalogued as rs1259138049; called by muse, mutect2
- FAM227A | c.*3731G>A | 3'UTR (SNP) | VAF 24/109 reads (22%) | catalogued as rs752413312; called by muse, mutect2, varscan2
- FOXRED1 | c.1102-47C>T | Intron (SNP) | VAF 59/246 reads (24%) | catalogued as COSV55006284; called by muse, mutect2, varscan2
- NOVA1 | c.280+45634G>A | Intron (SNP) | VAF 30/171 reads (18%) | called by muse, mutect2, varscan2
- NPIPB14P | chr16:69976728 C>G | 3'Flank (SNP) | VAF 13/333 reads (4%) | catalogued as rs1483095339; called by muse, mutect2
- PAQR6 | c.-93C>T | 5'UTR (SNP) | VAF 50/169 reads (30%) | called by muse, mutect2, varscan2
- SYNPR | c.540+1164G>A | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- TLE3 | c.24+122C>T | Intron (SNP) | VAF 24/171 reads (14%) | catalogued as rs751481224; called by muse, mutect2, varscan2
- TMED5 | c.471+240G>T | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as rs1161772037; called by muse, mutect2, varscan2
- TMEM150A | c.113+108C>G | Intron (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2, varscan2
